Somatic mutation profile of tumor specimen ALCH-AC6A-TTP1-A (aliquot ALCH-AC6A-TTP1-A-1-0-D-A49J-36) from ALCHEMIST case ALCH-AC6A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.8 years (23,674 days).
Specimen ALCH-AC6A-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 013eda9e-9c24-4fd4-84f3-e3f0366f9ff2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AC6A-NB1-A (Blood Derived Normal), aliquot ALCH-AC6A-NB1-A-1-0-D-A49J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/405eaffc-36ee-4901-892d-e476c0110374

The open-access MAF lists 41 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, Intron 2, Nonsense Mutation 2, 3'UTR 1, In Frame Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 162/1028 reads (16%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel
- COX15 | c.1076C>T p.T359I | Missense Mutation (SNP) | VAF 53/479 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as rs1479946370; called by muse, mutect2, varscan2
- DDX19B | c.595C>G p.R199G | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV55364728; called by muse, mutect2
- LYRM7 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs146610687; called by muse, mutect2
- MTRR | c.1354T>A p.L452M (on ENST00000264668; = p.L425M on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV52941681; called by muse, mutect2, varscan2
- PCDHGB2 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV53960203; called by muse, mutect2, varscan2
- PIK3CG | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 28/321 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0.011); catalogued as COSV63246064; called by muse, mutect2
- PTPRF | c.1354A>T p.T452S | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as rs958996158; called by muse, mutect2
- ZFHX4 | c.6538A>C p.T2180P | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51447480; called by muse, mutect2, varscan2
- ZNF106 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.075); catalogued as COSV99782060; called by muse, mutect2
- AL035461.3 | c.3005A>C p.K1002T | Missense Mutation (SNP) | VAF 40/383 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- AP2M1 | c.29A>T p.H10L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- APPBP2 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- ARPC5 | c.425T>G p.V142G | Missense Mutation (SNP) | VAF 42/628 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DLGAP4 | c.1672A>C p.K558Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FANCB | c.2212C>G p.L738V | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- LAMA2 | c.5834C>T p.A1945V | Missense Mutation (SNP) | VAF 54/861 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- LAMA2 | c.7627C>T p.P2543S | Missense Mutation (SNP) | VAF 40/606 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- MAGED1 | c.1744C>T p.L582F | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC17 | c.12389C>G p.P4130R | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- NCK2 | c.476G>A p.W159* | Nonsense Mutation (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- NT5C3A | c.744T>G p.H248Q (on ENST00000610140 / NM_001374335.1; = p.H214Q on NM_016489.13) | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2
- OPHN1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- OR10A6 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PI16 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.39); called by muse, mutect2
- PTPRK | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 92/1048 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); called by muse, mutect2
- REV1 | c.1912G>T p.D638Y | Missense Mutation (SNP) | VAF 37/568 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SEC24D | c.2873T>A p.L958* | Nonsense Mutation (SNP) | VAF 57/417 reads (14%) | called by muse, mutect2, varscan2
- TTC24 | c.965C>G p.A322G | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2
- TTC26 | c.74G>C p.R25T | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2
- ABCB7 | c.157C>A p.R53= | Silent (SNP) | VAF 30/385 reads (8%) | catalogued as rs368238673, COSV53719493; called by muse, mutect2
- RBMXL2 | c.702G>A p.S234= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs1190794791, COSV60978927; called by muse, mutect2
- REG1A | c.465A>G p.E155= | Silent (SNP) | VAF 18/276 reads (7%) | called by muse, mutect2
- SLC47A2 | c.417C>T p.L139= | Silent (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- TBX18 | c.483C>T p.I161= | Silent (SNP) | VAF 13/233 reads (6%) | called by muse, mutect2
- ZFHX3 | c.4827C>T p.S1609= | Silent (SNP) | VAF 35/412 reads (8%) | called by muse, mutect2
- AL353804.6 | chrX:73826367 G>T | 3'Flank (SNP) | VAF 50/1180 reads (4%) | called by muse, mutect2
- GSDME | c.*48C>T | 3'UTR (SNP) | VAF 13/373 reads (3%) | called by muse, mutect2
- SNX29P2 | n.1034G>T | RNA (SNP) | VAF 44/1059 reads (4%) | called by muse, mutect2
- SRSF7 | c.573-380C>T | Intron (SNP) | VAF 24/380 reads (6%) | called by muse, mutect2
- SYCP3 | c.200+32G>C | Intron (SNP) | VAF 21/460 reads (5%) | catalogued as rs761766368; called by muse, mutect2
